Somatic mutation profile of tumor specimen TCGA-CF-A1HS-01A (aliquot TCGA-CF-A1HS-01A-11D-A13W-08) from TCGA case TCGA-CF-A1HS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.5 years (27,565 days).
Specimen TCGA-CF-A1HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b066d537-75aa-4742-896e-0e2a164db321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A1HS-10A (Blood Derived Normal), aliquot TCGA-CF-A1HS-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4512dce4-ffca-49e8-886d-d6b3650ad5d0

The open-access MAF lists 258 somatic variants for this specimen: 182 protein-altering or splice-affecting, 69 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 69, Nonsense Mutation 13, Splice Site 7, Intron 3, Frame Shift Del 3, RNA 2, 3'Flank 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV59389012; called by muse, mutect2, varscan2
- ABCB4 | c.3634C>G p.L1212V (on ENST00000265723 / NM_018849.3; = p.L1205V on NM_000443.4) | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV55937612; called by muse, mutect2, varscan2
- ACSF3 | c.1431C>G p.I477M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58079586; called by muse, varscan2
- ADAMTS3 | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs756072715, COSV54395441; called by muse, mutect2, varscan2
- ADAMTS9 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 24/641 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV55784710, COSV99900020; called by muse, mutect2
- ADGRG4 | c.3826G>C p.E1276Q | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV104381503, COSV54960601, COSV54968673; called by muse, mutect2, varscan2
- AFF1 | c.1184T>A p.V395D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as COSV57121468; called by muse, mutect2, varscan2
- AKAP10 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56731969; called by muse, mutect2, varscan2
- ALDH9A1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV61339719; called by muse, mutect2, varscan2
- ANKFY1 | c.1905C>G p.S635R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV58919310; called by muse, mutect2, varscan2
- ASB17 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52411003; called by muse, mutect2, varscan2
- ATP6V1E1 | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53658816; called by muse, mutect2, varscan2
- AXIN2 | c.2018C>A p.T673N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs576688801, COSV61058578; called by muse, mutect2, varscan2
- BACH1 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV54519685, COSV54521571; called by muse, mutect2, varscan2
- BAHD1 | c.2331G>C p.K777N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60379084; called by muse, mutect2, varscan2
- BBS9 | c.1276-2A>T p.X426_splice | Splice Site (SNP) | VAF 29/134 reads (22%) | catalogued as COSV54175268; called by muse, mutect2, varscan2
- BCL9L | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.258); catalogued as COSV52686363; called by muse, mutect2, varscan2
- BDP1 | c.1493-1G>C p.X498_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV62432434; called by muse, mutect2, varscan2
- BRF1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs763667067, COSV59270603, COSV59272053; called by muse, mutect2, varscan2
- C5 | c.4768G>A p.A1590T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); catalogued as COSV56329411; called by muse, mutect2, varscan2
- CACNA1B | c.2257T>G p.S753A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV53134405; called by muse, mutect2, varscan2
- CAPSL | c.349A>T p.M117L | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV68438488; called by muse, mutect2
- CCDC142 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.059); catalogued as COSV51778729; called by muse, mutect2
- CCDC33 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV58354025, COSV58359279; called by muse, mutect2
- CD163 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV63134554; called by muse, mutect2
- CD200 | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59863756; called by muse, mutect2, varscan2
- CDH6 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1023796106, COSV54067368, COSV54073060; called by muse, mutect2
- CDKN1A | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV99781763; called by muse, mutect2
- CEP78 | c.1837C>G p.L613V (on ENST00000424347 / NM_001349840.2; = p.L614V on NM_032171.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV52848589; called by muse, mutect2, varscan2
- CEP97 | c.1875C>G p.F625L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59125681; called by muse, mutect2, varscan2
- CHAF1A | c.737T>G p.L246W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56673716; called by muse, mutect2, varscan2
- CHRNB3 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51492976; called by muse, mutect2, varscan2
- CIZ1 | c.1586G>C p.G529A | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV52972914; called by muse, mutect2
- CLHC1 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV68464387; called by muse, mutect2, varscan2
- CMC4 | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs782280954, COSV62899890; called by muse, mutect2
- CPXM1 | c.1115T>A p.L372H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV66046011; called by muse, mutect2, varscan2
- CSMD3 | c.6421A>C p.I2141L (on ENST00000297405 / NM_001363185.1; = p.I2037L on NM_052900.3) | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV52229781; called by muse, mutect2, varscan2
- CYBC1 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209390816; called by muse, mutect2
- CYP26A1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56418977; called by muse, mutect2, varscan2
- DAB1 | c.1480G>T p.D494Y (on ENST00000371231; = p.D461Y on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64694436; called by muse, varscan2
- DAB1 | c.1412G>C p.C471S (on ENST00000371231; = p.C438S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.138); catalogued as COSV64694443; called by muse, varscan2
- DAB1 | c.1356G>T p.Q452H (on ENST00000371231; = p.Q419H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64694449; called by muse, varscan2
- DAB1 | c.1243G>A p.G415S (on ENST00000371231; = p.G382S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV64694462; called by muse, varscan2
- DAP3 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58021610; called by muse, mutect2, varscan2
- DAW1 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59366940; called by muse, mutect2, varscan2
- DIS3L | c.2470A>G p.K824E (on ENST00000319212 / NM_001143688.3; = p.K741E on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59913171; called by muse, mutect2, varscan2
- DNAJC28 | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV58721873; called by muse, mutect2, varscan2
- ELF3 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.298); catalogued as COSV100668966; called by muse, mutect2
- EML2 | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55601304; called by muse, mutect2, varscan2
- EP400 | c.2613G>T p.Q871H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV57777264; called by muse, mutect2, varscan2
- EPB41L4B | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101000581, COSV65797652; called by muse, mutect2, varscan2
- EPN3 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52141017; called by muse, mutect2, varscan2
- EPS8 | c.1251-1G>A p.X417_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV55533096; called by muse, varscan2
- ERBB4 | c.1740C>A p.C580* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV53514819, COSV53527141; called by muse, mutect2
- EXO5 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56416008, COSV99591354; called by muse, mutect2
- FAM166A | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61117549; called by mutect2, varscan2
- FAM166A | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV61117573; called by muse, mutect2, varscan2
- FEM1A | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV54164282; called by muse, mutect2, varscan2
- FHOD1 | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as COSV50763370, COSV50767766; called by muse, mutect2
- FKBP5 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61882542; called by muse, mutect2
- FLG | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV64244013; called by muse, mutect2
- FOXP2 | c.1546-1G>C p.X516_splice | Splice Site (SNP) | VAF 16/157 reads (10%) | catalogued as COSV63488868; called by muse, mutect2
- GAD1 | c.1215G>C p.K405N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64026573; called by muse, mutect2, varscan2
- GARS1 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV66828722; called by muse, mutect2, varscan2
- GBF1 | c.4840G>C p.E1614Q (on ENST00000369983 / NM_001377137.1; = p.E1613Q on NM_004193.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64146571; called by muse, mutect2, varscan2
- GHDC | c.1226del p.A409Efs*37 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as COSV56988810; called by mutect2, pindel*, varscan2
- GMPS | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55808745, COSV55810427; called by muse, mutect2
- GNG2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58917511; called by muse, mutect2, varscan2
- GPR101 | c.996G>T p.M332I | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV53239445; called by muse, mutect2, varscan2
- GPR135 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV67749703; called by muse, mutect2, varscan2
- GSG1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV60970033, COSV60970738, COSV60973447; called by muse, mutect2
- GUCY2C | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1171511341, COSV53792062; called by muse, mutect2
- HDAC9 | c.2804A>T p.H935L | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV67777371; called by muse, mutect2, varscan2
- HK3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52841982; called by muse, mutect2, varscan2
- INSM2 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV51888291, COSV99355438; called by muse, mutect2, varscan2
- JAM2 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.297); catalogued as COSV57258624; called by muse, mutect2
- KBTBD6 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 37/204 reads (18%) | catalogued as rs1238706934; called by muse, mutect2, varscan2
- KCNAB1 | c.745-1G>T p.X249_splice (on ENST00000490337 / NM_172160.3; = p.X238_splice on NM_003471.3) | Splice Site (SNP) | VAF 12/157 reads (8%) | catalogued as rs1460443204, COSV56748564; called by muse, mutect2
- KIF13A | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV52456645; called by muse, mutect2
- KIF15 | c.1716G>C p.Q572H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58162410; called by muse, mutect2, varscan2
- KIF7 | c.3354G>C p.Q1118H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51543300; called by muse, mutect2, varscan2
- LGALS13 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV55680305; called by muse, mutect2, varscan2
- LILRA5 | c.87C>T p.L29= | Splice Region (SNP) | VAF 27/49 reads (55%) | catalogued as rs201892026, COSV56642271; called by muse, mutect2, varscan2
- LMOD2 | c.695T>C p.F232S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV71755714; called by muse, mutect2, varscan2
- LPIN1 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56767365; called by muse, mutect2, varscan2
- LY75 | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV55108416; called by muse, mutect2, varscan2
- MAGEA6 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV61449160; called by muse, mutect2, varscan2
- MALT1 | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61935498; called by muse, mutect2, varscan2
- MCC | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100203174, COSV56731393; called by muse, mutect2, varscan2
- MCTS1 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64892671; called by muse, mutect2, varscan2
- MED7 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1305015342, COSV53850330; called by muse, mutect2, varscan2
- MINDY1 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56499603; called by muse, mutect2
- MYH4 | c.4492C>G p.H1498D | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV55121185, COSV55125044; called by muse, mutect2
- MYLK | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as COSV60614286; called by muse, mutect2
- MYO6 | c.3596A>C p.K1199T (on ENST00000369981; = p.K1189T on NM_004999.4) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV64118494, COSV64119866; called by muse, mutect2
- NDC80 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55248711; called by muse, mutect2, varscan2
- NEK5 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV62880792, COSV62880818; called by muse, mutect2, varscan2
- NES | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV63961595; called by muse, mutect2
- NKTR | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as rs770047537, COSV51773174; called by muse, mutect2, varscan2
- NRIP1 | c.2867C>G p.S956C | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV59658581; called by muse, mutect2, varscan2
- NUP43 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61190484; called by muse, mutect2, varscan2
- OR10A5 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as COSV55054802, COSV55055162; called by muse, mutect2, varscan2
- OR5AK2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV58804809; called by muse, mutect2, varscan2
- OR9Q2 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs763920323, COSV61112210; called by muse, mutect2, varscan2
- PAIP1 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 17/206 reads (8%) | catalogued as COSV100166777; called by muse, mutect2
- PAPPA | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100074073, COSV60286876; called by muse, mutect2, varscan2
- PDE4DIP | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV57707000; called by mutect2, varscan2
- PLCG1 | c.3700G>C p.D1234H (on ENST00000373271 / NM_182811.2; = p.D1235H on NM_002660.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV54820549; called by muse, mutect2, varscan2
- PLPP3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV64839863; called by muse, varscan2
- PPT2 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV61354851; called by muse, mutect2, varscan2
- PRG4 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV66624573; called by muse, mutect2
- RGL2 | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV65842559; called by muse, varscan2
- RLF | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65652248; called by muse, mutect2, varscan2
- RND1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV59045640; called by muse, mutect2, varscan2
- RNF157 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.15); catalogued as COSV53945989; called by muse, mutect2, varscan2
- RNPEP | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV55242170; called by muse, mutect2, varscan2
- RORC | c.41-1G>A p.X14_splice | Splice Site (SNP) | VAF 25/133 reads (19%) | catalogued as COSV59093967; called by muse, mutect2, varscan2
- RPAP1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV58540607; called by muse, mutect2, varscan2
- SCYL3 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63046618; called by muse, mutect2, varscan2
- SEC14L3 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 119/184 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV53180087; called by muse, mutect2, varscan2
- SEC31B | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV64824945; called by muse, varscan2
- SEMA6C | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59004854; called by muse, mutect2, varscan2
- SETX | c.2147A>G p.K716R | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV56388796; called by muse, mutect2, varscan2
- SGO2 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV63415989; called by muse, mutect2, varscan2
- SKIL | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 29/434 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.438); catalogued as COSV52060766; called by muse, mutect2
- SLC2A5 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV66237335; called by muse, mutect2, varscan2
- SLC35F3 | c.293T>C p.F98S (on ENST00000366617 / NM_001300845.1; = p.F167S on NM_173508.4) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64020504; called by muse, mutect2, varscan2
- SLC9A2 | c.1804C>G p.R602G | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV52133887, COSV52139147; called by muse, mutect2
- SLF2 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV53275805; called by muse, mutect2, varscan2
- SLITRK6 | c.1220T>G p.F407C | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68390657; called by muse, mutect2, varscan2
- STRIP2 | c.1883C>G p.S628* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99973628; called by muse, mutect2
- SV2A | c.1453A>G p.K485E | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV64965269; called by muse, mutect2, varscan2
- SYNE1 | c.19749G>C p.Q6583H (on ENST00000367255 / NM_182961.4; = p.Q6512H on NM_033071.3) | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.18); catalogued as COSV55025128; called by muse, mutect2, varscan2
- TAP2 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.725); catalogued as COSV66500026; called by muse, mutect2, varscan2
- TBX3 | c.883G>C p.D295H (on ENST00000257566 / NM_016569.4; = p.D275H on NM_005996.4) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57473193; called by muse, mutect2, varscan2
- TCTN3 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV56448788; called by muse, mutect2
- TGS1 | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52701180; called by muse, mutect2, varscan2
- TGS1 | c.1895A>C p.N632T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV52701194; called by muse, mutect2, varscan2
- TIE1 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV65250275, COSV65250638; called by muse, mutect2
- TIGD3 | c.1282del p.L428Cfs*14 | Frame Shift Del (DEL) | VAF 43/81 reads (53%) | catalogued as COSV52889808; called by mutect2, pindel, varscan2
- TIMMDC1 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51787203; called by muse, mutect2, varscan2
- TLR5 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100643433, COSV60559582; called by muse, mutect2
- TMC3 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.154); catalogued as COSV63923644; called by muse, mutect2
- TPO | c.856T>A p.C286S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV61104959; called by muse, mutect2, varscan2
- TRO | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51503796; called by muse, mutect2, varscan2
- TRPS1 | c.2275C>G p.P759A (on ENST00000220888 / NM_001330599.2; = p.P772A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV55249307; called by muse, mutect2
- TRRAP | c.5167G>C p.G1723R (on ENST00000359863 / NM_001244580.1; = p.G1705R on NM_003496.3) | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.265); catalogued as COSV62848079; called by muse, mutect2
- TRRAP | c.9702G>T p.W3234C (on ENST00000359863 / NM_001244580.1; = p.W3205C on NM_003496.3) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62848092; called by muse, mutect2, varscan2
- TSPAN7 | c.472A>T p.N158Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV54532333; called by muse, mutect2, varscan2
- TTF2 | c.3244C>A p.H1082N | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65633022; called by muse, mutect2, varscan2
- TTN | c.46651G>A p.E15551K (on ENST00000591111; = p.E8127K on NM_003319.4) | Missense Mutation (SNP) | VAF 57/616 reads (9%) | PolyPhen benign (0.098); catalogued as COSV60167813; called by muse, mutect2
- TTN | c.9989-1G>C p.X3330_splice (on ENST00000591111; = p.X3284_splice on NM_003319.4) | Splice Site (SNP) | VAF 4/45 reads (9%) | catalogued as COSV60167846; called by muse, mutect2
- UBR1 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 10/276 reads (4%) | catalogued as COSV51931343; called by muse, mutect2
- VCX3B | c.698C>G p.P233R | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV66842839, COSV66842935; called by muse, mutect2
- VGLL4 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV56078819; called by muse, mutect2, varscan2
- WHRN | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs141863996; called by muse, mutect2, varscan2
- XPC | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); catalogued as COSV53204846, COSV53206007; called by muse, mutect2
- ZBP1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV59062882; called by muse, mutect2
- ZCCHC7 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.241); catalogued as COSV59719877; called by muse, mutect2
- ZNF236 | c.1386A>G p.I462M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1568210700, COSV53491452; called by muse, mutect2, varscan2
- ZNF616 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57511889; called by muse, mutect2
- ZNF780A | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV61815824; called by muse, mutect2
- ZNF816 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54411634; called by muse, mutect2, varscan2
- ADAM2 | c.2047A>T p.K683* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2626C>G p.Q876E | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.021); called by muse, mutect2
- EXOC3 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- HDAC6 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HSF1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ICA1L | c.1307C>G p.S436* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- INTS3 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 18/541 reads (3%) | called by muse, mutect2
- KDM6A | c.3185dup p.D1062Efs*2 | Frame Shift Ins (INS) | VAF 38/135 reads (28%) | called by mutect2, pindel, varscan2
- L3MBTL3 | c.1601C>G p.S534* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- LCE1F | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- NRIP1 | c.2122G>T p.E708* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- PAGE1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2
- PARD6A | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- PDE9A | c.889A>T p.R297W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2
- SUPT20HL1 | c.2594C>G p.P865R | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D8 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2
- TTN | c.16666_16679del p.V5556Lfs*13 (on ENST00000591111; = p.V4629Lfs*13 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, pindel
- ZNF319 | c.1593G>C p.K531N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTL9 | c.297C>G p.G99= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ADGRL2 | c.2163G>A p.R721= (on ENST00000370717 / NM_001366005.1; = p.R708= on NM_012302.4) | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV54675032; called by muse, mutect2, varscan2
- AK8 | c.1287C>G p.V429= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- APOL1 | c.421C>T p.L141= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV59869363; called by muse, mutect2, varscan2
- ARL6IP5 | c.417G>A p.L139= | Silent (SNP) | VAF 26/873 reads (3%) | catalogued as COSV56235305; called by muse, mutect2
- ATP13A5 | c.2430C>T p.N810= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs112958471, COSV60871436; called by muse, mutect2, varscan2
- BICD1 | c.1101G>A p.R367= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV55682316; called by muse, mutect2, varscan2
- BMPR2 | c.2031C>G p.L677= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV65810874; called by muse, mutect2, varscan2
- BRIP1 | c.2829C>T p.V943= | Silent (SNP) | VAF 49/401 reads (12%) | catalogued as rs767164240, COSV52002367; ClinVar: likely benign; called by muse, mutect2, varscan2
- C8orf74 | c.456G>A p.P152= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV58754781; called by muse, mutect2, varscan2
- CACNA1I | c.4233C>T p.F1411= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as COSV60812496; called by muse, mutect2, varscan2
- CCDC18 | c.1467A>G p.E489= | Silent (SNP) | VAF 39/235 reads (17%) | catalogued as COSV58145025; called by muse, mutect2, varscan2
- CHST12 | c.381G>C p.V127= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV51676406; called by muse, mutect2, varscan2
- CLN8 | c.588G>A p.L196= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV58670955; called by muse, mutect2, varscan2
- CSTF2T | c.1035C>G p.V345= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV58656906; called by muse, mutect2, varscan2
- CYP2W1 | c.426G>A p.P142= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs760484267, COSV58270670; called by muse, mutect2, varscan2
- DAB1 | c.1095G>T p.V365= (on ENST00000371231; = p.V332= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV64694471; called by muse, varscan2
- EPS8L2 | c.822G>A p.Q274= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV59346785, COSV59348887; called by muse, mutect2, varscan2
- GAB4 | c.951G>A p.K317= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV68754358; called by muse, mutect2, varscan2
- GPR35 | c.111C>G p.L37= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1419650268, COSV60577749; called by muse, mutect2, varscan2
- HRC | c.825C>A p.G275= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV53257318; called by muse, mutect2, varscan2
- INHBA | c.264A>G p.R88= | Silent (SNP) | VAF 22/606 reads (4%) | catalogued as COSV54222858; called by muse, mutect2
- INPP5F | c.237A>G p.G79= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV62822272; called by muse, mutect2, varscan2
- KCND3 | c.867C>G p.L289= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV56177365, COSV56183921; called by muse, mutect2, varscan2
- KCNK3 | c.738C>T p.F246= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV100257084; called by muse, mutect2, varscan2
- KLF5 | c.816G>A p.Q272= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV66614835; called by muse, mutect2, varscan2
- KRI1 | c.654G>A p.L218= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs140755508; called by muse, mutect2, varscan2
- KRT6A | c.1332G>A p.L444= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV58106272; called by muse, mutect2, varscan2
- LAMC3 | c.1725G>C p.L575= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV63093132; called by muse, mutect2, varscan2
- LHFPL5 | c.129C>G p.L43= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV64178223, COSV64178780; called by muse, mutect2, varscan2
- LIMS2 | c.306C>T p.C102= (on ENST00000355119 / NM_001161403.3; = p.C126= on NM_017980.4) | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs375926340; called by muse, mutect2, varscan2
- MARVELD3 | c.636C>T p.I212= | Silent (SNP) | VAF 187/290 reads (64%) | catalogued as COSV51705098; called by muse, mutect2, varscan2
- MED13 | c.6420C>G p.L2140= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV101181519, COSV67264941; called by muse, mutect2
- MLLT3 | c.84C>T p.F28= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV63498972; called by muse, mutect2, varscan2
- MRPL22 | c.606C>T p.I202= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs370756659; called by muse, mutect2
- NAE1 | c.879C>G p.R293= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV51977088; called by muse, mutect2
- NPY2R | c.1062C>A p.S354= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV61528182, COSV61528752; called by muse, mutect2, varscan2
- OR11L1 | c.840G>T p.V280= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV63314895; called by muse, mutect2, varscan2
- ORMDL1 | c.393C>G p.L131= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV57877170; called by muse, mutect2, varscan2
- OSR2 | c.447C>A p.G149= | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as COSV52557835; called by muse, mutect2
- PARD6A | c.600G>C p.G200= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV54668734; called by muse, mutect2, varscan2
- PCSK1 | c.1125G>C p.T375= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100227144, COSV60735197; called by muse, mutect2, varscan2
- PDE1C | c.1977G>A p.L659= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV58518749; called by muse, mutect2, varscan2
- PLPP3 | c.321G>A p.R107= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV64839865; called by muse, mutect2, varscan2
- POGZ | c.2724C>T p.L908= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV51852216; called by muse, mutect2, varscan2
- PPP6R2 | c.1197C>G p.L399= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as COSV53290802, COSV53294300; called by muse, mutect2, varscan2
- RASGRP2 | c.1359C>T p.I453= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV62449956; called by muse, varscan2
- SACS | c.2889T>C p.S963= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV66542935; called by muse, mutect2, varscan2
- SAMD9 | c.3042G>A p.E1014= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as COSV66076399, COSV66077409; called by muse, mutect2, varscan2
- SELENBP1 | c.870G>A p.V290= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as rs1175756479, COSV64373703; called by muse, mutect2
- TBX19 | c.1026C>G p.T342= | Silent (SNP) | VAF 14/195 reads (7%) | catalogued as COSV63197894; called by muse, mutect2
- TLR8 | c.2433G>A p.G811= (on ENST00000218032 / NM_138636.5; = p.G829= on NM_016610.4) | Silent (SNP) | VAF 31/226 reads (14%) | catalogued as COSV54319003; called by muse, mutect2, varscan2
- TMEM200A | c.1134C>G p.A378= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV51655420; called by muse, mutect2, varscan2
- TMEM54 | c.42G>C p.R14= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV61276016; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1899C>T p.L633= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1419612158, COSV64100781; called by muse, mutect2, varscan2
- TNXB | c.11112G>A p.V3704= (on ENST00000647633; = p.V3457= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV64482438; called by muse, mutect2, varscan2
- TP53 | c.816G>A p.V272= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs756421198, COSV52918960, COSV53313340, COSV53438396; called by muse, mutect2, varscan2
- TRABD2A | c.429C>T p.R143= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs370950603; called by muse, varscan2
- TRABD2A | c.369C>T p.L123= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV59104188; called by muse, varscan2
- TRPM4 | c.1929C>G p.L643= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV53262592, COSV53265266; called by muse, mutect2, varscan2
- UNC13C | c.2988C>T p.S996= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV52893185; called by muse, mutect2
- URGCP | c.1194G>C p.L398= (on ENST00000453200 / NM_001077663.3; = p.L389= on NM_017920.4) | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV56249351; called by muse, mutect2
- USP6NL | c.1545C>T p.L515= | Silent (SNP) | VAF 25/189 reads (13%) | catalogued as rs1049263419, COSV53213048, COSV53213481; called by muse, mutect2, varscan2
- VASH1 | c.609C>T p.R203= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV99388272; called by muse, mutect2
- VPS13A | c.2599A>C p.R867= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV62432732; called by muse, mutect2, varscan2
- ZC3H7A | c.2316T>C p.F772= | Silent (SNP) | VAF 25/247 reads (10%) | catalogued as COSV63270264; called by muse, mutect2, varscan2
- ZNF233 | c.1329G>A p.Q443= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV61934003; called by muse, mutect2, varscan2
- ZNF354C | c.873G>C p.L291= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as COSV59608040, COSV59608844; called by muse, mutect2, varscan2
- ZNF594 | c.1203G>A p.E401= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as COSV101280525, COSV68385733; called by muse, mutect2
- AL645933.1 | chr6:31463993 A>G | 5'Flank (SNP) | VAF 63/151 reads (42%) | called by muse, mutect2, varscan2
- C3orf35 | chr3:37417324 G>C | 3'Flank (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- CSNK1G2 | c.-266+12571G>C | Intron (SNP) | VAF 70/135 reads (52%) | catalogued as COSV55338626, COSV99730326; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14651G>C | Intron (SNP) | VAF 7/63 reads (11%) | catalogued as rs1188984811, COSV100234601; called by muse, mutect2, varscan2
- MIR422A | n.83C>T | RNA (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- SNX29P2 | n.806G>C | RNA (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.-147+12139A>T | Intron (SNP) | VAF 12/192 reads (6%) | catalogued as COSV62626499; called by muse, mutect2
